Gene-level copy-number profile of tumor specimen TCGA-13-1504-01A from TCGA case TCGA-13-1504, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 68.5 years (25,008 days).
Specimen TCGA-13-1504-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.e210eee4-4d99-4bc0-bbe4-09f143bc1f2c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-1504-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/39bab40f-f20b-4d45-b75d-e9d660cce092

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 114; copy number 1: 710; copy number 2: 7,205; copy number 3: 10,617; copy number 4: 16,690; copy number 5: 13,439; copy number 6: 5,166; copy number 7: 3,133; copy number 8: 683; copy number 9: 532; copy number 10: 418; copy number 11: 114; copy number 12: 175; copy number 13: 701; copy number 14: 9; copy number 15: 7; copy number 17: 40; copy number 19: 43; copy number 20: 2; copy number 21: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-1504-01A-01D-0472-01): tumor purity 0.49, ploidy 4.27, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,057 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:161,600,438–163,361,563, 7 genes, copy number 13–20 (within-gene range 8–20): AC112770.1, AC131211.1, TOMM22P6, AC128716.1, AC128685.1, LINC01192, RPS6P4.
- chr3:165,772,904–167,066,320, 16 genes, copy number 21 (within-gene range 15–21): BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1, PPIAP74.
- chr3:168,094,049–174,378,005, 100 genes, copy number 11–17 (broad region; genes not listed).
- chr3:174,631,823–174,632,064, 1 gene, copy number 13: RN7SKP40.
- chr4:71,741,696–75,101,943, 55 genes, copy number 14–19: GC, RNA5SP163, AC068721.1, NPFFR2, ADAMTS3, AC095056.1, HNRNPA1P67, RNU4ATAC9P, RNU6ATAC5P, COX18, ANKRD17, HMGA1P2, AC053527.2, AC053527.1, AC108157.1, ALB, AFP, AFM, LINC02499, AC074250.1, RASSF6, UMLILO, CXCL8, AC112518.1, CXCL6, PPBPP1, PF4V1, CXCL1, HNRNPA1P55, CXCL1P1, PF4, PPBP, CXCL5, AC097709.1, RN7SL218P, CXCL3, PPBPP2, AC093677.3, AC093677.1, CXCL2, MTHFD2L, AC093677.2, EPGN, EREG, AC021180.1, AREG, AC239584.1, BTC, AC098825.1, HSPE1P23, PARM1, PARM1-AS1, AC110760.1, LINC02562, AC110760.2.
- chr4:85,475,150–86,002,668, 2 genes, copy number 13 (within-gene range 2–13): ARHGAP24, MIR4451.
- chr5:25,963,839–52,804,044, 325 genes, copy number 9–12 (within-gene range 8–12) (broad region; genes not listed).
- chr5:52,853,183–52,872,925, 1 gene, copy number 9 (within-gene range 5–9): AC022133.2.
- chr5:53,413,504–55,307,694, 40 genes, copy number 10–13: AC108114.1, FST, NDUFS4, LINC02105, ASS1P9, AC025175.1, ARL15, AC025175.2, RNU6-272P, MIR581, RN7SL801P, AC016601.1, AC008873.1, LINC01033, RPL37P25, HSPB3, SNX18, AC016583.1, AC016583.2, CSPG4BP, AC112198.1, AC112198.3, AC112198.2, ESM1, AC034238.1, GZMK, Y_RNA, AC034238.3, AC034238.2, GZMAP1, GZMA, CDC20B, GPX8, MIR449A, MIR449B, MIR449C, MCIDAS, CCNO, AC026704.1, DHX29.
- chr6:57,314,805–57,646,850, 3 genes, copy number 9: PRIM2, MIR548U, FO680682.1.
- chr7:69,125,270–70,793,506, 10 genes, copy number 10 (within-gene range 5–10): RNU6-832P, AC069280.2, AC092100.1, AC069280.1, MTCO2P25, MTCO1P25, RNU6-229P, Y_RNA, CT66, AUTS2.
- chr7:130,266,863–131,948,953, 47 genes, copy number 12 (within-gene range 8–12): CPA2, CPA4, CPA5, CPA1, CEP41, AC007938.1, MESTIT1, MEST, AC007938.5, AC007938.6, AC007938.4, AC007938.2, MIR335, COPG2, AC007938.3, AUXG01000058.1, RNA5SP246, AC234644.1, TSGA13, AC234644.2, KLF14, AC016831.5, AC016831.6, AC016831.2, H4P1, AC016831.3, LINC00513, MIR29A, AC016831.1, MIR29B1, AC016831.4, AC058791.1, LINC-PINT, RNU6-1010P, MKLN1, AC009362.1, MKLN1-AS, AC008264.2, PODXL, AC008264.1, EEF1B2P6, AC093106.1, AC093106.2, NDUFB9P2, CAPZA1P4, AC009518.2, AC009518.1.
- chr12:137,411–34,249,958, 848 genes, copy number 10–13 (broad region; genes not listed).
- chr17:28,018,770–28,702,679, 54 genes, copy number 13 (within-gene range 2–13): AC090287.1, AC090287.2, SNORA70, NLK, Vault, RPS29P22, AC061975.8, AC061975.7, PYY2, ERVE-1, AC061975.6, PPY2P, AC061975.2, AC061975.4, AC061975.1, AC061975.5, AC061975.3, KRT18P55, TMEM97, IFT20, TNFAIP1, POLDIP2, TMEM199, AC002094.1, MIR4723, AC002094.2, SEBOX, AC002094.3, SARM1, VTN, AC002094.4, AC002094.5, SLC46A1, AC015917.2, H3P41, AC015917.1, AC005726.1, RPS7P1, SLC13A2, FOXN1, UNC119, PIGS, ALDOC, AC005726.3, SPAG5, SPAG5-AS1, RSKR, AC005726.4, KIAA0100, AC005726.2, SDF2, RPS12P28, SUPT6H, AC010761.3.
- chr17:59,331,655–60,170,899, 39 genes, copy number 13: YPEL2, AC091059.2, MIR4729, AC091059.1, LINC01476, RNU4-13P, DHX40, AC091271.1, CLTC, PTRH2, VMP1, AC040904.1, MIR21, RNU6-450P, TUBD1, NDUFB8P2, RPS6KB1, RPS29P21, AC005702.1, RNFT1, TBC1D3P1-DHX40P1, RNFT1-DT, DHX40P1, TBC1D3P1, AC005702.5, AC005702.4, AC005702.3, HEATR6, MIR4737, AC005702.2, AC025048.4, WFDC21P, AC025048.6, AC025048.3, AC025048.2, AC025048.5, AC025048.7, AC025048.1, CA4.
- chr17:60,231,516–60,245,647, 2 genes, copy number 13: SCARNA20, AC104763.1.
- chr17:61,354,763–64,662,307, 116 genes, copy number 13 (within-gene range 3–13) (broad region; genes not listed).
- chr18:22,586,465–23,486,603, 15 genes, copy number 10 (within-gene range 7–10): RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA.
- chr18:26,655,737–27,190,698, 1 gene, copy number 10 (within-gene range 7–10): AQP4-AS1.
- chr18:26,852,043–28,177,946, 15 genes, copy number 10 (within-gene range 7–10): AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1, AC006249.1.
- chr19:21,483,374–23,147,221, 83 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr22:18,906,028–21,977,632, 182 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr22:29,720,003–31,750,140, 94 genes, copy number 9 (broad region; genes not listed).
- chr22:31,757,202–31,757,498, 1 gene, copy number 9: RN7SL20P.

Autosomal genes at a single copy (total copy number 1): 274. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
